Somatic mutation profile of tumor specimen SM-JU33T (aliquot 7316UP-1848) from CPTAC case C761370, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen SM-JU33T: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fbb553bf-e9c6-4868-9dce-df466245c660.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105210 (Blood Derived Normal), aliquot 7316UP-1848-1105210; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/792f8a97-af4f-45dc-929d-63403809b1a7

The open-access MAF lists 55 somatic variants for this specimen: 40 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 12, Intron 2, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 82/128 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCY1 | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 63/406 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs80190930, COSV52035709; called by muse, mutect2, varscan2
- ANKRD18B | c.1667G>A p.R556H | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs544682999, COSV52094798; called by muse, mutect2, varscan2
- ATP11A | c.1079T>C p.I360T | Missense Mutation (SNP) | VAF 154/358 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52119601; called by muse, mutect2, varscan2
- C1orf158 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs750241731, COSV55346815, COSV55347143, COSV99847419; called by muse, mutect2
- C9orf135 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 20/73 reads (27%) | catalogued as rs372154813; called by muse, mutect2, varscan2
- CXorf58 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.066); catalogued as rs764370346; called by muse, mutect2, varscan2
- CYP2A7 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 83/251 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs763421114; called by muse, mutect2, varscan2
- DSP | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 113/289 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.881); catalogued as rs760502491; called by muse, mutect2, varscan2
- INSYN2B | c.541G>T p.G181C | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs987708755, COSV56939632; called by muse, mutect2, varscan2
- KCNH5 | c.1892G>A p.R631Q | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs970741080, COSV59759638; called by muse, mutect2, varscan2
- LRRC49 | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs766840882, COSV53008716; called by muse, varscan2
- OR52N5 | c.557C>T p.T186M | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs766003251, COSV57699403; called by muse, mutect2, varscan2
- OR5D18 | c.373G>A p.V125M | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as rs770766899, COSV100450944; called by muse, mutect2, varscan2
- OXR1 | c.1192G>C p.D398H (on ENST00000442977 / NM_001198532.1; = p.D397H on NM_018002.3) | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.182); catalogued as COSV100367502; called by muse, mutect2, varscan2
- PCDHGA7 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 98/267 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.26); catalogued as COSV53927246; called by muse, mutect2, varscan2
- POLR3B | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 96/232 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.244); catalogued as rs145075371; called by muse, mutect2, varscan2
- RNF216 | c.1583C>T p.T528M (on ENST00000425013 / NM_207116.3; = p.T585M on NM_207111.4) | Missense Mutation (SNP) | VAF 39/251 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs144654379; called by muse, mutect2, varscan2
- SCLT1 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs372095705; called by muse, mutect2
- SH3TC2 | c.2551C>T p.R851W | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs144655516; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SHOX | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 173/430 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as rs758706054, COSV61860840; called by muse, mutect2, varscan2
- SULF2 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs753117627; called by muse, mutect2, varscan2
- SULT2B1 | c.857C>T p.T286M (on ENST00000201586 / NM_177973.2; = p.T271M on NM_004605.2) | Missense Mutation (SNP) | VAF 98/284 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750776892; called by muse, mutect2
- TECRL | c.439T>C p.F147L | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1171468238; called by muse, mutect2, varscan2
- TTLL7 | c.2317C>T p.R773C | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1191689608, COSV53081769; called by muse, mutect2, varscan2
- WNT2 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 145/860 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.124); catalogued as rs779778873, COSV55410380; called by muse, mutect2, varscan2
- ZNF536 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 103/326 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100835448; called by muse, mutect2, varscan2
- BAHCC1 | c.5725G>A p.D1909N | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CHAT | c.692A>G p.Q231R | Missense Mutation (SNP) | VAF 183/284 reads (64%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- FBN2 | c.4717G>T p.D1573Y | Missense Mutation (SNP) | VAF 88/278 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRAS1 | c.6892A>G p.T2298A | Missense Mutation (SNP) | VAF 90/297 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- HOXA1 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 244/704 reads (35%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IL7R | c.1310T>G p.I437S | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- LRFN2 | c.1783C>G p.P595A | Missense Mutation (SNP) | VAF 72/179 reads (40%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEE2 | c.229A>G p.R77G | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SOS2 | c.64C>G p.L22V | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SRSF4 | c.800G>A p.S267N | Missense Mutation (SNP) | VAF 233/630 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SSTR5 | c.419C>A p.A140E | Missense Mutation (SNP) | VAF 133/355 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- THSD7A | c.2335G>A p.D779N | Missense Mutation (SNP) | VAF 52/416 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); called by muse, mutect2
- TSC22D2 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 79/192 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CFAP20DC | c.1242G>A p.Q414= (on ENST00000482387 / NM_001351530.2; = p.Q289= on NM_198463.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 49/126 reads (39%) | called by muse, mutect2, varscan2
- FREM1 | c.4113T>G p.L1371= | Silent (SNP) | VAF 65/205 reads (32%) | catalogued as rs1284219939; called by muse, mutect2, varscan2
- GPR156 | c.1443T>C p.D481= | Silent (SNP) | VAF 108/283 reads (38%) | called by muse, mutect2, varscan2
- LGALS9C | c.1041C>T p.G347= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs774275104; called by mutect2, varscan2
- NDRG1 | c.705C>T p.R235= | Silent (SNP) | VAF 196/560 reads (35%) | catalogued as rs528436514; called by muse, mutect2, varscan2
- NEIL3 | c.1062A>G p.E354= | Silent (SNP) | VAF 40/119 reads (34%) | called by muse, mutect2, varscan2
- PCDHA2 | c.1527G>A p.S509= | Silent (SNP) | VAF 265/730 reads (36%) | catalogued as COSV65370386; called by muse, mutect2, varscan2
- PCDHA7 | c.1509G>A p.A503= | Silent (SNP) | VAF 274/693 reads (40%) | catalogued as COSV65347773; called by muse, mutect2, varscan2
- PCDHB9 | c.1629C>T p.S543= | Silent (SNP) | VAF 355/855 reads (42%) | catalogued as rs373422120, COSV53379717; called by muse, mutect2, varscan2
- SGCE | c.801G>A p.P267= (on ENST00000647096; = p.P231= on NM_003919.3) | Silent (SNP) | VAF 70/467 reads (15%) | catalogued as rs757206832, COSV56018366; ClinVar: likely benign; called by muse, mutect2, varscan2
- TMEM132D | c.471C>T p.D157= | Silent (SNP) | VAF 177/388 reads (46%) | catalogued as rs139627769; called by muse, mutect2, varscan2
- TRPC7 | c.480C>T p.R160= | Silent (SNP) | VAF 44/150 reads (29%) | called by muse, mutect2, varscan2
- LINC01387 | n.355G>A | RNA (SNP) | VAF 94/259 reads (36%) | called by muse, mutect2, varscan2
- NDRG1 | c.206-35T>C | Intron (SNP) | VAF 87/212 reads (41%) | called by muse, mutect2, varscan2
- SEC23A | c.1308+34G>T | Intron (SNP) | VAF 56/155 reads (36%) | called by muse, mutect2, varscan2
